Somatic mutation profile of tumor specimen TCGA-B4-5835-01A (aliquot TCGA-B4-5835-01A-11D-1669-08) from TCGA case TCGA-B4-5835, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 64.1 years (23,408 days).
Specimen TCGA-B4-5835-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 881cee8f-6dae-4f4d-bddc-63ee6da0acc8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B4-5835-10A (Blood Derived Normal), aliquot TCGA-B4-5835-10A-01D-1669-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86a73e27-f3f5-4fbc-ba58-91dac74f67b5

The open-access MAF lists 74 somatic variants for this specimen: 64 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Nonsense Mutation 12, Frame Shift Del 8, Silent 7, Intron 3, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA8 | c.3737G>T p.R1246L | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.769); catalogued as rs576031209, COSV52200542; called by muse, mutect2, varscan2
- ABCC8 | c.1604C>T p.A535V | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.158); catalogued as COSV56849914; called by muse, mutect2, varscan2
- ADAM15 | c.538G>T p.A180S | Missense Mutation (SNP) | VAF 47/198 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV55059069; called by muse, mutect2, varscan2
- AMER1 | c.2498A>T p.D833V | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV57660121; called by muse, mutect2, varscan2
- AOC2 | c.2006A>G p.D669G (on ENST00000253799 / NM_009590.4; = p.D642G on NM_001158.5) | Missense Mutation (SNP) | VAF 133/227 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745592498, COSV53826328, COSV53827910; called by muse, mutect2, varscan2
- ATP6V0D1 | c.401G>A p.S134N | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.95); catalogued as COSV52097598; called by muse, mutect2, varscan2
- ATR | c.7420G>A p.G2474R | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63386269; called by muse, mutect2, varscan2
- AZU1 | c.706C>T p.R236* | Nonsense Mutation (SNP) | VAF 10/122 reads (8%) | catalogued as rs112572343, COSV52140944; called by muse, mutect2
- BCL9L | c.2483T>A p.V828E | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV52684118; called by muse, mutect2, varscan2
- CALD1 | c.2002C>A p.Q668K (on ENST00000361675 / NM_033138.4; = p.Q413K on NM_004342.7) | Missense Mutation (SNP) | VAF 11/264 reads (4%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.533); catalogued as COSV62645946; called by muse, mutect2
- CDR1 | c.741G>C p.W247C | Missense Mutation (SNP) | VAF 61/275 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV65164178; called by muse, mutect2, varscan2
- CELSR1 | c.5770C>T p.R1924C | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs770227748, COSV53089408; called by mutect2, varscan2
- CFAP47 | c.2314C>A p.H772N | Missense Mutation (SNP) | VAF 31/177 reads (18%) | SIFT tolerated (0.79); PolyPhen benign (0.2); catalogued as COSV52884122; called by muse, mutect2, varscan2
- ELAPOR2 | c.2551G>C p.V851L (on ENST00000450689 / NM_001142749.3; = p.V684L on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT tolerated (0.96); PolyPhen benign (0.174); catalogued as COSV51886486; called by muse, mutect2
- FGG | c.53T>A p.L18* | Nonsense Mutation (SNP) | VAF 32/125 reads (26%) | catalogued as COSV60195256; called by muse, mutect2, varscan2
- FO393400.1 | c.448T>G p.L150V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV54070112; called by muse, mutect2, varscan2
- GP2 | c.640G>A p.D214N (on ENST00000381362 / NM_001007240.3; = p.D211N on NM_001502.4) | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as rs143098544, COSV56893820; called by muse, mutect2, varscan2
- HERC1 | c.8114C>A p.S2705Y | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT tolerated (1); PolyPhen possibly damaging (0.506); catalogued as COSV71247668; called by muse, mutect2, varscan2
- KCNQ1 | c.1071G>T p.Q357H | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV50107556; called by muse, mutect2, varscan2
- KLRG2 | c.835A>T p.I279F | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.7); catalogued as COSV61800753; called by muse, mutect2, varscan2
- LRRK2 | c.5286C>G p.F1762L | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV100111373; called by muse, mutect2, varscan2
- MEGF11 | c.1212G>T p.Q404H | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as COSV56550000; called by muse, mutect2, varscan2
- MMEL1 | c.1105G>T p.D369Y | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.905); catalogued as COSV56521251; called by muse, mutect2, varscan2
- MMP27 | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as rs1469299137, COSV52780717; called by muse, mutect2, varscan2
- NLRP14 | c.1367A>C p.D456A | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV55066782; called by muse, mutect2, varscan2
- NOX1 | c.1167T>A p.S389R | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99471783; called by muse, mutect2, varscan2
- OR2B11 | c.310C>A p.Q104K | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV59510078, COSV59510094; called by muse, mutect2, varscan2
- OR7D2 | c.492G>A p.M164I | Missense Mutation (SNP) | VAF 51/255 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); catalogued as COSV60139677; called by muse, mutect2, varscan2
- PCDH1 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.946); catalogued as rs145360303; called by muse, mutect2, varscan2
- PCDH11X | c.2374G>A p.A792T | Missense Mutation (SNP) | VAF 51/228 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53462706, COSV53495158; called by muse, mutect2, varscan2
- PDZD4 | c.1067G>A p.R356H | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV51246601; called by muse, mutect2, varscan2
- PLEC | c.12931C>T p.Q4311* (on ENST00000322810 / NM_201380.4; = p.Q4201* on NM_000445.5) | Nonsense Mutation (SNP) | VAF 25/92 reads (27%) | catalogued as COSV100519824; called by muse, mutect2, varscan2
- PLOD3 | c.313G>T p.D105Y | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs750298633, COSV56182725; called by muse, mutect2, varscan2
- PPEF1 | c.1210G>T p.E404* | Nonsense Mutation (SNP) | VAF 21/123 reads (17%) | catalogued as COSV62995660; called by muse, mutect2, varscan2
- PSG7 | c.352G>T p.G118* | Nonsense Mutation (SNP) | VAF 98/433 reads (23%) | catalogued as COSV68445029; called by muse, mutect2, varscan2
- PTPRR | c.1375G>T p.E459* | Nonsense Mutation (SNP) | VAF 17/70 reads (24%) | catalogued as COSV51731152; called by muse, mutect2, varscan2
- SETD2 | c.2329G>T p.E777* | Nonsense Mutation (SNP) | VAF 13/125 reads (10%) | catalogued as COSV57437015; called by muse, mutect2, varscan2
- SETD2 | c.1679C>A p.S560* | Nonsense Mutation (SNP) | VAF 40/148 reads (27%) | catalogued as COSV57437029, COSV57442585, COSV57443759; called by muse, mutect2, varscan2
- SIRT7 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 34/57 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as COSV60815328; called by muse, mutect2, varscan2
- SLC6A11 | c.1864A>T p.I622F | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as COSV54393114; called by muse, mutect2, varscan2
- SLF2 | c.3142C>T p.L1048F | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53273393; called by muse, mutect2, varscan2
- SLITRK6 | c.820G>T p.E274* | Nonsense Mutation (SNP) | VAF 30/80 reads (38%) | catalogued as COSV68390103; called by muse, mutect2, varscan2
- SYNE1 | c.2062G>T p.G688W (on ENST00000367255 / NM_182961.4; = p.G695W on NM_033071.3) | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54972373; called by muse, mutect2, varscan2
- SYNE2 | c.1528G>T p.G510W | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59949645; called by muse, mutect2, varscan2
- SYNJ2 | c.974G>T p.C325F | Missense Mutation (SNP) | VAF 16/249 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV62897140; called by muse, mutect2
- THNSL1 | c.1145C>T p.T382I | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867823531, COSV64479282; called by muse, mutect2, varscan2
- TLR8 | c.1834G>T p.E612* (on ENST00000218032 / NM_138636.5; = p.E630* on NM_016610.4) | Nonsense Mutation (SNP) | VAF 16/208 reads (8%) | catalogued as COSV54317802; called by muse, mutect2
- TMOD3 | c.217C>A p.L73M | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57941694, COSV57943666; called by muse, mutect2, varscan2
- TTN | c.72202G>T p.D24068Y (on ENST00000591111; = p.D16644Y on NM_003319.4) | Missense Mutation (SNP) | VAF 29/173 reads (17%) | PolyPhen probably damaging (0.999); catalogued as rs772757849, COSV59895434, COSV60033636; called by muse, mutect2, varscan2
- TUT4 | c.1381C>T p.R461* | Nonsense Mutation (SNP) | VAF 3/18 reads (17%) | catalogued as COSV99932933; called by muse, varscan2
- VAV1 | c.2349T>G p.Y783* | Nonsense Mutation (SNP) | VAF 35/129 reads (27%) | catalogued as COSV58382982; called by muse, mutect2, varscan2
- VWF | c.6799-2A>G p.X2267_splice | Splice Site (SNP) | VAF 9/36 reads (25%) | catalogued as COSV54619114; called by muse, mutect2, varscan2
- XRRA1 | c.1220C>A p.P407H | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58497634; called by muse, mutect2
- ZNF479 | c.566A>C p.K189T | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV58638151; called by muse, mutect2, varscan2
- ZSCAN18 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.175); catalogued as COSV53732826; called by muse, mutect2
- ANKRD26 | c.1251del p.E417Dfs*21 | Frame Shift Del (DEL) | VAF 18/75 reads (24%) | called by mutect2, pindel, varscan2
- BTF3 | c.602_605del p.S201* (on ENST00000380591 / NM_001037637.1; = p.S157* on NM_001207.4) | Frame Shift Del (DEL) | VAF 24/74 reads (32%) | called by mutect2, pindel, varscan2
- CD2 | c.717del p.K239Nfs*18 | Frame Shift Del (DEL) | VAF 11/53 reads (21%) | called by mutect2, pindel, varscan2
- DBR1 | c.587del p.F196Sfs*10 | Frame Shift Del (DEL) | VAF 11/82 reads (13%) | called by mutect2, pindel, varscan2
- FLCN | c.1261del p.S421Afs*47 | Frame Shift Del (DEL) | VAF 5/20 reads (25%) | called by mutect2, pindel, varscan2
- NPHP3 | c.3740del p.K1247Rfs*18 | Frame Shift Del (DEL) | VAF 26/137 reads (19%) | called by mutect2, pindel, varscan2
- PRKG1 | c.1679del p.G560Efs*3 | Frame Shift Del (DEL) | VAF 14/76 reads (18%) | called by mutect2, pindel, varscan2
- RRP12 | c.2502+1del p.X834_splice | Splice Site (DEL) | VAF 16/65 reads (25%) | called by mutect2, pindel, varscan2
- TRAV8-2 | c.102del p.G35Efs*6 | Frame Shift Del (DEL) | VAF 23/109 reads (21%) | called by mutect2, pindel, varscan2
- DNAH3 | c.6681T>C p.I2227= | Silent (SNP) | VAF 16/107 reads (15%) | catalogued as COSV54519705; called by muse, mutect2, varscan2
- MSLN | c.531G>A p.L177= | Silent (SNP) | VAF 30/47 reads (64%) | catalogued as COSV53501780; called by muse, mutect2, varscan2
- PLEC | c.12930G>A p.E4310= (on ENST00000322810 / NM_201380.4; = p.E4200= on NM_000445.5) | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as COSV100519831; called by muse, mutect2, varscan2
- SYNDIG1 | c.198G>A p.R66= | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as rs1003799591, COSV65234607; called by muse, mutect2, varscan2
- TACC2 | c.7779T>C p.H2593= (on ENST00000334433; = p.H671= on NM_006997.4) | Silent (SNP) | VAF 33/132 reads (25%) | catalogued as COSV53280756; called by muse, mutect2, varscan2
- VPS13A | c.8898C>T p.G2966= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as COSV62429198; called by muse, mutect2, varscan2
- WASF2 | c.156A>G p.G52= | Silent (SNP) | VAF 39/97 reads (40%) | catalogued as COSV71005463; called by muse, mutect2, varscan2
- KHK | c.210-303G>A | Intron (SNP) | VAF 19/107 reads (18%) | catalogued as rs775197292, COSV53154683; called by muse, mutect2, varscan2
- KIF1B | c.2115+7240T>A | Intron (SNP) | VAF 29/66 reads (44%) | catalogued as COSV99824330; called by muse, mutect2, varscan2
- RAVER1 | c.1431+38del | Intron (DEL) | VAF 4/14 reads (29%) | called by mutect2, varscan2
